TCGA case TCGA-DX-A1L4 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c66f5f5-3e37-4353-b0f8-64b92a733da8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,195 days); Year of diagnosis: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 10; Tumor length measurement: 14; Tumor width measurement: 12.8.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8.5; Tumor length measurement: 19.5; Tumor width measurement: 15.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 61.7 years (22,535 days); Days to diagnosis: 340 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 340 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 340 days.
- Days to follow up: 1,294 days (3.5 years); Disease response: With Tumor.
- Days to follow up: 2,036 days (5.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 908.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A1L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-DX-A1L4-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-DX-A1L4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A1L4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Disease multifocal indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,036 days; disease-specific survival: no event (censored), 2,036 days; disease-free interval: event (new tumor event after initially disease-free), 340 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 340 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A1L4-01A-12D-A26F-01): tumor purity 0.22, ploidy 2.06, whole-genome doublings 0.
